Somatic mutation profile of tumor specimen MMRF_2302_1_BM_CD138pos (aliquot MMRF_2302_1_BM_CD138pos_T1_KHS5U_K13999) from MMRF case MMRF_2302, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.7 years (28,367 days).
Specimen MMRF_2302_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e03bc34-c933-4305-a50d-86f34ec5a4c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2302_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2302_1_PB_Whole_C1_KHS5U_K13998; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce51f4e-fe01-46de-9e7a-5d92fcc77c01

The open-access MAF lists 177 somatic variants for this specimen: 68 protein-altering or splice-affecting, 16 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 43, Intron 21, Silent 16, 5'UTR 15, 3'Flank 7, Nonsense Mutation 5, 5'Flank 4, Splice Region 3, RNA 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RP1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786205589, CM1312797, CM149188, COSV99607784; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM8 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs367803725; called by muse, mutect2, varscan2
- ATAD5 | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 152/186 reads (82%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs552886395, COSV58974514; called by muse, mutect2, varscan2
- CFAP157 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs368112775; called by muse, mutect2, varscan2
- CYSRT1 | c.128C>T p.P43L (on ENST00000409414; = p.P3L on NM_199001.5) | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100763146; called by muse, mutect2
- DBX2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1048740449; called by muse, mutect2, varscan2
- DNAH8 | c.7268C>T p.P2423L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs369613804; called by muse, mutect2, varscan2
- DYSF | c.2570G>T p.W857L | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50268706; called by muse, mutect2
- EFCAB2 | c.664G>A p.E222K (on ENST00000366522; = p.E86K on NM_032328.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV63656465; called by muse, mutect2, varscan2
- FAM71E2 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1327011222; called by muse, mutect2
- FBLN2 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as rs543515573; called by muse, mutect2, varscan2
- IGHJ3 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 28/30 reads (93%) | catalogued as rs190137342; called by muse, varscan2
- KRTAP24-1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs781497652, COSV61089192; called by muse, mutect2, varscan2
- LLGL2 | c.2177-6C>T | Splice Region (SNP) | VAF 9/20 reads (45%) | catalogued as rs561039690; called by muse, mutect2, varscan2
- OPN4 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs760158575; called by muse, mutect2, varscan2
- OTUD7A | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1355082202, COSV61035943; called by muse, mutect2, varscan2
- PARP15 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.407); catalogued as COSV71827737; called by muse, mutect2, varscan2
- PCDH11Y | c.2694G>A p.M898I (on ENST00000400457 / NM_032973.2; = p.M887I on NM_032971.3) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV53078721; called by muse, mutect2, varscan2
- SSBP3 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV62572423; called by muse, varscan2
- TAS2R40 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs199829808; called by muse, mutect2, varscan2
- TEX15 | c.1288G>A p.E430K (on ENST00000256246; = p.E813K on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56346889; called by muse, mutect2
- TMSB4X | c.-17+1G>T | Splice Site (SNP) | VAF 59/60 reads (98%) | catalogued as COSV66081196, COSV66081636; called by muse, mutect2, varscan2
- XKR4 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 101/222 reads (45%) | catalogued as COSV59318960; called by muse, mutect2, varscan2
- ZNF485 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 129/153 reads (84%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62424618; called by muse, mutect2, varscan2
- ACSM2A | c.1267T>A p.F423I (on ENST00000219054; = p.F344I on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTS12 | c.2086G>A p.G696R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BHLHE41 | c.730_740delinsTAC p.G244Yfs*253 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by pindel, varscan2*
- BTBD18 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CDKL4 | c.239T>G p.F80C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFHR4 | c.445G>A p.D149N (on ENST00000367416 / NM_001201551.2; = p.D150N on NM_001201550.3) | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CHD1L | c.1246G>C p.V416L | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- CRKL | c.413A>T p.D138V | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL4A | c.2118_2122del p.M706Ifs*6 (on ENST00000375440 / NM_001008895.4; = p.M606Ifs*6 on NM_003589.3) | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by mutect2, pindel, varscan2
- DHRS9 | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX40 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DSC1 | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 62/189 reads (33%) | called by muse, mutect2, varscan2
- EXOC3 | c.1777-7T>A | Splice Region (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- FAM76B | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); called by muse, mutect2
- FMN1 | c.3377+8T>A | Splice Region (SNP) | VAF 51/213 reads (24%) | called by muse, mutect2, varscan2
- GLO1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C4 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF11 | c.412C>G p.L138V (on ENST00000393775 / NM_001015887.3; = p.L137V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- JRK | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- KRTAP4-6 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- MAGEL2 | c.2923A>G p.T975A | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- MAP3K4 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MDN1 | c.13297T>C p.S4433P | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MLH1 | c.1838A>G p.E613G | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- MPDZ | c.4223G>A p.G1408E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPPED2 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2
- MRPL55 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.31828G>C p.V10610L | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.119); called by muse, mutect2
- NAA30 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- OR4C16 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 126/438 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- P3H4 | c.295T>A p.W99R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- PCDH15 | c.5444C>T p.P1815L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PHC3 | c.1265C>G p.P422R (on ENST00000494943 / NM_001308116.2; = p.P434R on NM_024947.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2
- PRRC2C | c.5246C>A p.P1749Q (on ENST00000367742; = p.P1747Q on NM_015172.4) | Missense Mutation (SNP) | VAF 191/600 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RASA2 | c.196A>T p.I66L | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.22); called by muse, mutect2
- SPEN | c.7900T>G p.S2634A | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.746); called by muse, mutect2
- ST6GAL2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STXBP5L | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNDIG1 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 103/114 reads (90%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5D | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- USF3 | c.4612T>G p.L1538V | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VEZF1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 89/138 reads (64%) | called by muse, mutect2, varscan2
- ZNF317 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- ZNF527 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BCL9L | c.717C>T p.F239= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs368576803; called by muse, mutect2
- COL7A1 | c.1215C>T p.P405= | Silent (SNP) | VAF 51/176 reads (29%) | catalogued as rs200882719; called by muse, mutect2, varscan2
- COMP | c.210C>T p.D70= | Silent (SNP) | VAF 135/508 reads (27%) | catalogued as rs1448899276; called by muse, mutect2, varscan2
- CYP4F8 | c.1119C>T p.D373= | Silent (SNP) | VAF 93/164 reads (57%) | catalogued as rs367977820; called by muse, mutect2, varscan2
- DNAAF5 | c.2166C>T p.C722= | Silent (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- HERC2 | c.2373G>A p.V791= | Silent (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- IRS2 | c.3009C>T p.D1003= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs1196151093; called by muse, mutect2, varscan2
- KBTBD13 | c.444C>T p.Y148= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1474666301; called by muse, mutect2, varscan2
- NR2F2 | c.258G>T p.S86= | Silent (SNP) | VAF 81/359 reads (23%) | called by muse, mutect2, varscan2
- PDE4DIP | c.4167G>A p.S1389= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs781923977, COSV57697979, COSV57717926; called by muse, mutect2, varscan2
- PEG10 | c.357C>T p.C119= (on ENST00000482108 / NM_001040152.2; = p.C153= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/299 reads (34%) | called by muse, mutect2, varscan2
- PHLPP1 | c.4401G>A p.P1467= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as rs564548477; called by muse, mutect2, varscan2
- PIGB | c.882C>T p.N294= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs781588106; called by muse, mutect2, varscan2
- PLSCR3 | c.159C>T p.P53= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- PTCH2 | c.2892C>T p.F964= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SOX6 | c.2466G>A p.P822= (on ENST00000528429 / NM_001145819.2; = p.P795= on NM_017508.3) | Silent (SNP) | VAF 100/155 reads (65%) | catalogued as rs201395591; called by muse, mutect2, varscan2
- ABLIM1 | c.800+66C>T | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- AC006971.1 | n.4401C>T | RNA (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2, varscan2
- AC241929.1 | chr1:146865012 A>C | 5'Flank (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- AP1M1 | c.-33C>G | 5'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ATP2A2 | c.*842G>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.307-423T>A | Intron (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2
- BDH2 | c.419-378A>C | Intron (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- BMPR1B | chr4:95157188 C>T | 3'Flank (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- C11orf87 | c.*4849T>G | 3'UTR (SNP) | VAF 63/97 reads (65%) | called by muse, mutect2, varscan2
- C18orf54 | c.*2776T>C | 3'UTR (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- C9orf129 | n.470G>A | RNA (SNP) | VAF 12/34 reads (35%) | catalogued as rs745502503; called by mutect2, varscan2
- CADM1 | chr11:115504484 G>A | 5'Flank (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- CBLN2 | c.*135C>A | 3'UTR (SNP) | VAF 41/41 reads (100%) | called by muse, mutect2, varscan2
- CD46 | c.*1100G>C | 3'UTR (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- CDK6 | c.*8725T>A | 3'UTR (SNP) | VAF 54/167 reads (32%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137016839 T>G | 3'Flank (SNP) | VAF 116/179 reads (65%) | called by muse, mutect2, varscan2
- COBL | c.1096+19826T>C | Intron (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- COL7A1 | c.*17T>C | 3'UTR (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- DGKB | c.2307+472T>G | Intron (SNP) | VAF 79/132 reads (60%) | called by muse, mutect2, varscan2
- DGKZ | c.-70G>A | 5'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- DHX38 | c.512-86T>G | Intron (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- EFR3B | c.2142+206G>T | Intron (SNP) | VAF 39/83 reads (47%) | catalogued as rs1223674602; called by muse, mutect2, varscan2
- ELF5 | c.385+1399C>T | Intron (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- EPS8L2 | c.*474G>C | 3'UTR (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- FADS2 | c.*1388A>C | 3'UTR (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- FBN1 | c.6998-109G>C | Intron (SNP) | VAF 83/315 reads (26%) | catalogued as rs1365254741; called by muse, mutect2, varscan2
- FIBIN | c.-197C>T | 5'UTR (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100590451; called by muse, mutect2, varscan2
- FXYD7 | c.*83G>A | 3'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- GCSAML | c.*2789A>G | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- GLP2R | c.*79G>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs938550263; called by muse, mutect2, varscan2
- HGF | c.865+486G>T | Intron (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- HOXA13 | c.*393G>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- HSD17B4 | c.1649-106C>T | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- HSPA12A | c.*2262C>T | 3'UTR (SNP) | VAF 47/87 reads (54%) | catalogued as rs138118199, COSV104427422; called by muse, mutect2, varscan2
- IGLL5 | c.-39T>A | 5'UTR (SNP) | VAF 24/26 reads (92%) | catalogued as rs535311226, COSV73249685; called by muse, varscan2
- IGLL5 | c.-15T>G | 5'UTR (SNP) | VAF 31/32 reads (97%) | called by muse, varscan2
- IQSEC1 | c.*1358G>A | 3'UTR (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- IRS4 | c.-40C>T | 5'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- ISCU | c.*205T>C | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- KCNG1 | c.*9G>A | 3'UTR (SNP) | VAF 26/52 reads (50%) | catalogued as rs776244568; called by muse, mutect2, varscan2
- KIAA0232 | c.*2269T>G | 3'UTR (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*2398C>T | 3'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- KIF21B | chr1:200972339 C>T | 3'Flank (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- KRAS | c.*216A>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs1475823212; called by muse, mutect2, varscan2
- L3MBTL1 | c.1193-51T>C | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- LETM1 | c.*55G>A | 3'UTR (SNP) | VAF 12/288 reads (4%) | catalogued as rs957136736; called by muse, mutect2
- LGALS8 | c.*11C>A | 3'UTR (SNP) | VAF 60/166 reads (36%) | called by muse, mutect2, varscan2
- LGR5 | c.*1258T>C | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- LZIC | chr1:9929673 C>T | 3'Flank (SNP) | VAF 6/68 reads (9%) | catalogued as rs1274638667; called by muse, mutect2
- MAF | c.*732_*754delinsTAGCATTGTTATGCTAAAATAGAGA | 3'UTR (INS) | VAF 6/59 reads (10%) | called by pindel, varscan2*
- MANF | c.-23G>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- MAU2 | c.1309-150A>G | Intron (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- MFNG | c.*112G>A | 3'UTR (SNP) | VAF 73/159 reads (46%) | called by muse, mutect2, varscan2
- MFSD8 | c.-1T>A | 5'UTR (SNP) | VAF 126/259 reads (49%) | called by muse, mutect2, varscan2
- MIR3150B | n.78C>T | RNA (SNP) | VAF 19/28 reads (68%) | catalogued as rs1047602453; called by muse, mutect2, varscan2
- MOGAT3 | chr7:101201833 C>T | 5'Flank (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- MRTFA | c.242-136A>T | Intron (SNP) | VAF 101/232 reads (44%) | called by muse, mutect2, varscan2
- MSANTD4 | c.*868C>T | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- NDUFS7 | c.228+612C>T | Intron (SNP) | VAF 67/248 reads (27%) | catalogued as rs746155263; called by muse, mutect2, varscan2
- NEBL | c.*3561dup | 3'UTR (INS) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.*346T>C | 3'UTR (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- OR10W1 | c.-343T>A | 5'UTR (SNP) | VAF 26/86 reads (30%) | catalogued as rs1027615038; called by muse, mutect2, varscan2
- PCDH7 | c.-949C>T | 5'UTR (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- PCNT | c.*39G>A | 3'UTR (SNP) | VAF 79/159 reads (50%) | catalogued as COSV64027332; called by muse, mutect2, varscan2
- PDHA1 | c.*1995G>C | 3'UTR (SNP) | VAF 84/86 reads (98%) | called by muse, mutect2, varscan2
- PEG3 | c.*2319C>T | 3'UTR (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- PGBD5 | chr1:230322209 G>A | 3'Flank (SNP) | VAF 39/100 reads (39%) | catalogued as rs1422928355; called by muse, mutect2, varscan2
- PHF19 | c.*1278A>G | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PI4KB | c.1520+13C>A | Intron (SNP) | VAF 71/107 reads (66%) | called by muse, mutect2, varscan2
- PPP4R3A | chr14:91510413 G>C | 5'Flank (SNP) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- PROS1 | c.-70G>A | 5'UTR (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- RAB10 | c.*960C>T | 3'UTR (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- RALB | c.*313C>T | 3'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- RBM46 | c.1403-799T>C | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- RGL3 | c.34-80G>A | Intron (SNP) | VAF 8/36 reads (22%) | catalogued as rs1283426651; called by muse, mutect2, varscan2
- RGS12 | c.4114+361G>A | Intron (SNP) | VAF 39/70 reads (56%) | catalogued as rs1027473936; called by muse, mutect2, varscan2
- RGS2 | c.*456G>C | 3'UTR (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- SERPINB8 | c.*1982dup | 3'UTR (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- SH3PXD2B | c.*2563A>G | 3'UTR (SNP) | VAF 56/149 reads (38%) | catalogued as rs979423272; called by muse, mutect2, varscan2
- SLC16A12 | c.*1551G>C | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- SLC5A8 | c.*1100G>T | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- SOWAHA | c.*1379C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SOX6 | chr11:15970687 C>T | 3'Flank (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- TBC1D9 | c.*504_*509del | 3'UTR (DEL) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- TLL1 | c.169+45803G>C | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- TM4SF20 | c.*865G>A | 3'UTR (SNP) | VAF 37/94 reads (39%) | catalogued as rs767040561; called by muse, mutect2, varscan2
- TMPRSS13 | chr11:117900940 C>G | 3'Flank (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- TOP3A | c.-180G>A | 5'UTR (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- TPD52 | c.-172T>G | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- XRCC5 | c.-14T>G | 5'UTR (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.3608-51A>T | Intron (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1802T>G | 3'UTR (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- ZXDB | c.-93T>C | 5'UTR (SNP) | VAF 44/52 reads (85%) | catalogued as rs1488894217; called by muse, varscan2
